Somatic mutation profile of tumor specimen TCGA-TM-A84G-01A (aliquot TCGA-TM-A84G-01A-11D-A36O-08) from TCGA case TCGA-TM-A84G, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 54.8 years (20,014 days).
Specimen TCGA-TM-A84G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a5f68ff-157f-4a75-953e-4c011c97df12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84G-10A (Blood Derived Normal), aliquot TCGA-TM-A84G-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d1772e5-03bd-4845-b9fa-99d00c1ff55b

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 46/84 reads (55%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2ML1 | c.3839C>T p.S1280L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as COSV100229144; called by muse, mutect2, varscan2
- CACNA1H | c.6940G>A p.V2314I | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs370867825; called by muse, mutect2, varscan2
- CCDC150 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV99777134; called by muse, mutect2, varscan2
- CDH18 | c.1472A>G p.E491G | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.097); catalogued as rs764106750, COSV56946810, COSV99936386; called by muse, mutect2, varscan2
- CELF3 | c.1354A>G p.K452E | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99310436; called by muse, mutect2, varscan2
- EGF | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs768479710, COSV54483010; called by muse, mutect2, varscan2
- IL13RA1 | c.828C>T p.Y276= | Splice Region (SNP) | VAF 62/161 reads (39%) | catalogued as rs747651648, COSV100861730; called by muse, mutect2, varscan2
- IL18RAP | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV99962175; called by muse, mutect2, varscan2
- IRF8 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99236652; called by muse, mutect2, varscan2
- MAGEB6 | c.893A>T p.N298I | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100983783; called by muse, mutect2, varscan2
- MAP7D3 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 53/120 reads (44%) | catalogued as COSV100286470; called by muse, mutect2, varscan2
- NOTCH1 | c.3592T>A p.C1198S | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99489578; called by muse, mutect2, varscan2
- OR10AD1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs1030942946, COSV59612520; called by muse, mutect2, varscan2
- PRICKLE1 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100566516; called by muse, mutect2, varscan2
- PRICKLE2 | c.410C>T p.P137L (on ENST00000295902; = p.P81L on NM_198859.4) | Missense Mutation (SNP) | VAF 120/237 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99897617; called by muse, mutect2, varscan2
- SPTLC3 | c.643G>T p.V215L | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as COSV100983227; called by muse, mutect2, varscan2
- SYAP1 | c.713T>A p.L238* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as COSV101204959; called by muse, mutect2, varscan2
- TG | c.3301A>G p.K1101E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765156801, COSV99601827; called by muse, mutect2, varscan2
- TPBG | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63882669; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs200888244; called by muse, mutect2, varscan2
- USP39 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as COSV100083923; called by muse, mutect2, varscan2
- WNK3 | c.3251C>A p.P1084Q | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV100671647; called by muse, mutect2, varscan2
- CENPE | c.6137_6139del p.R2046del | In Frame Del (DEL) | VAF 24/70 reads (34%) | called by pindel, varscan2
- FUBP1 | c.1308del p.I436Mfs*8 | Frame Shift Del (DEL) | VAF 40/59 reads (68%) | called by mutect2, pindel, varscan2
- RXFP2 | c.1694dup p.N565Kfs*15 | Frame Shift Ins (INS) | VAF 28/85 reads (33%) | called by mutect2, pindel, varscan2
- TRBV28 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- GOPC | c.867T>A p.V289= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99271083; called by muse, mutect2, varscan2
- ISM1 | c.555C>T p.D185= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs377766422; called by muse, mutect2, varscan2
- LRRK1 | c.3315C>T p.D1105= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs371351101; called by muse, mutect2, varscan2
- PTCHD3 | c.1392T>C p.S464= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs567074756, COSV101438928; called by muse, mutect2, varscan2
- PTX4 | c.948C>T p.Y316= (on ENST00000447419 / NM_001328608.2; = p.Y311= on NM_001013658.1) | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs777476588, COSV53520869; called by muse, mutect2, varscan2
- SPATA31D1 | c.4272T>C p.D1424= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs770814660, COSV100782885; called by muse, mutect2, varscan2
